Somatic mutation profile of tumor specimen BA2313D (aliquot aq-BA2313D) from BEATAML1.0 case 2104, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.7 years (16,703 days).
Specimen BA2313D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcc55ad5-e5d5-4661-87ea-3309af1584c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2819D (Solid Tissue Normal), aliquot aq-BA2819D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a070efab-64ea-45f7-9c45-96ce2c153bb2

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 48/111 reads (43%) | catalogued as rs387906632, CM117933, COSV62007611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.1598C>T p.S533L (on ENST00000460911 / NM_001203247.2; = p.S538L on NM_004456.5) | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV57446300; called by muse, mutect2, varscan2
- FGF8 | c.451G>T p.V151L (on ENST00000344255 / NM_033164.4; = p.V133L on NM_006119.6) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1367620386; called by muse, mutect2
- HYDIN | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1244006572; called by mutect2, varscan2
- OR4K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150686832, COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- SFXN1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs1201704038; called by muse, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 19/99 reads (19%) | catalogued as rs749403447; called by mutect2, varscan2
- CSMD2 | c.9239G>A p.R3080K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DDX28 | c.573G>T p.L191F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); called by muse, mutect2
- NUP98 | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.486); called by muse, mutect2
- NYNRIN | c.3974C>A p.A1325D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ZNF184 | c.764G>T p.C255F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADRA1D | c.60A>G p.A20= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- KIF13A | c.4227A>G p.P1409= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs1180737667; called by muse, mutect2, varscan2
- TANC1 | c.2499G>A p.L833= | Silent (SNP) | VAF 18/36 reads (50%) | called by mutect2, varscan2
- TMEM88 | c.355C>T p.L119= | Silent (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- RHOF | chr12:121797627 C>A | 5'Flank (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- ZFHX3 | c.-897+3591G>A | Intron (SNP) | VAF 29/80 reads (36%) | catalogued as rs1028324630; called by muse, mutect2, varscan2
